Somatic mutation profile of tumor specimen TCGA-B6-A0IK-01A (aliquot TCGA-B6-A0IK-01A-12W-A071-09) from TCGA case TCGA-B6-A0IK, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 63.4 years (23,150 days).
Specimen TCGA-B6-A0IK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c9e5211-39c9-4969-b962-237ed109069c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0IK-10A (Blood Derived Normal), aliquot TCGA-B6-A0IK-10A-01W-A071-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e63c687-2657-433c-b339-72818d5b7c85

The open-access MAF lists 148 somatic variants for this specimen: 97 protein-altering or splice-affecting, 45 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 45, Nonsense Mutation 9, Splice Site 2, 5'Flank 2, 5'UTR 2, Frame Shift Ins 2, Intron 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 68/322 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1057519891, COSV57247504, COSV57260861, COSV57263527; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 118/341 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PMS2 | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 20/212 reads (9%) | catalogued as rs63750871, CM950967, COSV99764106; ClinVar: pathogenic; called by muse, mutect2
- SMAD2 | c.1391C>G p.S464* | Nonsense Mutation (SNP) | VAF 17/65 reads (26%) | hotspot (GDC flag); catalogued as COSV50992836, COSV50992894, COSV50993280; called by muse, mutect2, varscan2
- TP53 | c.581T>G p.L194R | Missense Mutation (SNP) | VAF 18/78 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519998, COSV52663681, COSV52677924, COSV52679257, COSV52713187; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.8652C>G p.F2884L | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs771480876, COSV71291147; called by muse, mutect2, varscan2
- ADNP | c.1041G>A p.M347I | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV62426100; called by muse, mutect2, varscan2
- AGTPBP1 | c.2323C>T p.Q775* (on ENST00000357081 / NM_001330701.2; = p.Q735* on NM_015239.2) | Nonsense Mutation (SNP) | VAF 24/134 reads (18%) | catalogued as COSV61274288; called by muse, mutect2, varscan2
- AKAP13 | c.2512C>T p.R838W | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs748198504, COSV63463713; called by muse, mutect2, varscan2
- ARHGAP9 | c.642G>C p.Q214H | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as COSV62723641; called by muse, mutect2, varscan2
- ARID4B | c.3053C>G p.S1018* | Nonsense Mutation (SNP) | VAF 62/258 reads (24%) | catalogued as COSV51607055; called by muse, mutect2, varscan2
- ASB11 | c.68dup p.F24Lfs*2 | Frame Shift Ins (INS) | VAF 28/148 reads (19%) | catalogued as rs770804405; called by mutect2, varscan2
- BAZ2A | c.5366G>A p.R1789Q | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs200742397, COSV51639781; called by muse, mutect2, varscan2
- BAZ2B | c.1039C>G p.P347A | Missense Mutation (SNP) | VAF 75/297 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.344); catalogued as COSV58604949; called by muse, mutect2, varscan2
- BTN2A2 | c.478C>T p.Q160* | Nonsense Mutation (SNP) | VAF 8/79 reads (10%) | catalogued as rs994888288, COSV100760344; called by muse, mutect2, varscan2
- C16orf89 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV60124858; called by muse, mutect2, varscan2
- C6orf62 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV65290885; called by muse, mutect2, varscan2
- CBLB | c.952C>G p.Q318E | Missense Mutation (SNP) | VAF 52/256 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV51431000; called by muse, mutect2, varscan2
- CC2D1A | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.711); catalogued as rs747172992, COSV58781765; called by muse, mutect2, varscan2
- CDO1 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 123/561 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.139); catalogued as COSV51665776; called by muse, mutect2, varscan2
- CHEK1 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV54022744; called by muse, mutect2
- CNTN2 | c.976C>T p.Q326* | Nonsense Mutation (SNP) | VAF 18/94 reads (19%) | catalogued as COSV59351302; called by muse, mutect2, varscan2
- CRYGC | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.247); catalogued as rs780109947, COSV52204876; called by muse, mutect2, varscan2
- CSGALNACT2 | c.737G>C p.R246T | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.741); catalogued as COSV100989855, COSV65676025; called by muse, mutect2, varscan2
- DGAT2 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.427); catalogued as rs139005829, COSV57176525; called by muse, mutect2, varscan2
- DNAH11 | c.10783G>A p.E3595K | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs762731249, COSV60966050; called by muse, mutect2, varscan2
- DRP2 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as COSV65810993; called by muse, mutect2, varscan2
- ECM2 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 108/465 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs778924845, COSV60741855; called by muse, mutect2, varscan2
- EML5 | c.368C>A p.S123* | Nonsense Mutation (SNP) | VAF 42/217 reads (19%) | catalogued as COSV100715487, COSV61348355; called by muse, mutect2, varscan2
- EPC1 | c.245A>G p.N82S | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.536); catalogued as COSV53927598; called by muse, mutect2, varscan2
- GALNT9 | c.1705G>C p.E569Q (on ENST00000328957 / NM_001122636.2; = p.E203Q on NM_021808.3) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100201271; called by muse, mutect2, varscan2
- GOLGB1 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 53/250 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.105); catalogued as COSV61467874; called by muse, mutect2, varscan2
- GPR142 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs766708510, COSV59519286; called by muse, mutect2, varscan2
- GPR85 | c.806G>T p.R269I | Missense Mutation (SNP) | VAF 51/219 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.972); catalogued as COSV51784434; called by muse, mutect2, varscan2
- GPRASP1 | c.3577C>T p.R1193* | Nonsense Mutation (SNP) | VAF 95/349 reads (27%) | catalogued as COSV64356027; called by muse, mutect2, varscan2
- HCN1 | c.576G>C p.M192I | Missense Mutation (SNP) | VAF 66/326 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.089); catalogued as COSV57522708, COSV57536689; called by muse, mutect2, varscan2
- HMGN2 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.116); catalogued as COSV52577478; called by muse, mutect2, varscan2
- HMGN2 | c.68G>A p.R23K | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.105); catalogued as COSV52577485; called by muse, varscan2
- HOOK1 | c.1261G>C p.D421H | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as rs1431424485, COSV64619863; called by muse, mutect2, varscan2
- IGKV3-11 | c.232A>G p.I78V | Missense Mutation (SNP) | VAF 86/319 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.12); catalogued as rs576234259; called by muse, mutect2, varscan2
- IL17RA | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV60054820, COSV60055635; called by muse, mutect2, varscan2
- IMPG2 | c.3247G>A p.E1083K | Missense Mutation (SNP) | VAF 60/337 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV51974431; called by muse, mutect2, varscan2
- KCNT2 | c.2512G>T p.E838* | Nonsense Mutation (SNP) | VAF 35/154 reads (23%) | catalogued as COSV54091802; called by muse, mutect2, varscan2
- KIF1B | c.3958C>T p.R1320W (on ENST00000377086 / NM_001365952.1; = p.R1274W on NM_015074.3) | Missense Mutation (SNP) | VAF 133/315 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs764473301, COSV55805818; called by muse, mutect2, varscan2
- KLF3 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV54711539; called by muse, mutect2, varscan2
- KLHL38 | c.1474C>G p.L492V | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as COSV58088212; called by muse, mutect2, varscan2
- KMT2E | c.4478G>A p.R1493Q | Missense Mutation (SNP) | VAF 58/221 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs1206046791, COSV57576326; called by muse, mutect2, varscan2
- KRTAP4-12 | c.160G>C p.V54L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.138); catalogued as COSV67458064; called by muse, mutect2, varscan2
- LARS1 | c.933G>A p.M311I (on ENST00000394434 / NM_020117.11; = p.M284I on NM_016460.3) | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99198541; called by muse, mutect2
- LIFR | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV54694102; called by muse, mutect2, varscan2
- LRP1B | c.6536G>A p.G2179E | Missense Mutation (SNP) | VAF 128/453 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as rs1379417709, COSV101259241, COSV67226136; called by muse, mutect2, varscan2
- LZTS1 | c.1135G>C p.E379Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56117361, COSV56117539; called by muse, mutect2, varscan2
- MAGEB3 | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 55/205 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64397415; called by muse, mutect2, varscan2
- METTL7B | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs769045151, COSV57697604; called by muse, mutect2, varscan2
- MGAM | c.4918G>C p.E1640Q | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV72075066; called by muse, mutect2, varscan2
- MROH9 | c.26-1G>A p.X9_splice | Splice Site (SNP) | VAF 61/272 reads (22%) | catalogued as rs187983561, COSV63012310; called by muse, mutect2, varscan2
- MUC16 | c.30878G>A p.G10293E | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV67478339; called by muse, mutect2, varscan2
- MYOM3 | c.3993G>C p.K1331N | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV58396885, COSV58400347; called by muse, mutect2, varscan2
- NBEA | c.2858C>T p.A953V | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.956); catalogued as COSV59800876; called by muse, mutect2, varscan2
- NMNAT2 | c.14C>A p.T5N | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV55083770; called by muse, mutect2, varscan2
- NPHP1 | c.1222C>T p.R408C (on ENST00000393272 / NM_207181.4; = p.R409C on NM_000272.5) | Missense Mutation (SNP) | VAF 56/258 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs753700300, COSV57209901; called by muse, mutect2, varscan2
- NPHP1 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 21/212 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as COSV100337961; called by muse, mutect2, varscan2
- ODF2 | c.426G>C p.K142N (on ENST00000434106 / NM_153433.2; = p.K118N on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.669); catalogued as COSV63547998; called by muse, mutect2, varscan2
- OR13C2 | c.306C>G p.F102L | Missense Mutation (SNP) | VAF 94/535 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV73377745; called by muse, mutect2, varscan2
- PLPPR1 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 70/796 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs1333911204, COSV100883197; called by muse, mutect2
- PPP1R3A | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 48/234 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52881758; called by muse, mutect2, varscan2
- RBBP6 | c.3235C>G p.Q1079E | Missense Mutation (SNP) | VAF 30/289 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV60506657; called by muse, mutect2
- RGS22 | c.2011G>A p.E671K | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62664505; called by muse, mutect2, varscan2
- RIMS1 | c.3019G>A p.D1007N | Missense Mutation (SNP) | VAF 33/232 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.219); catalogued as COSV99325726; called by muse, mutect2, varscan2
- RLF | c.2264C>T p.S755L | Missense Mutation (SNP) | VAF 35/319 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV65652373; called by muse, mutect2, varscan2
- ROPN1L | c.622C>G p.L208V | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56874281; called by muse, mutect2, varscan2
- RUFY3 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.956); catalogued as rs748059452, COSV56915316; called by muse, mutect2, varscan2
- SARDH | c.2163G>A p.L721= | Splice Region (SNP) | VAF 4/12 reads (33%) | catalogued as COSV100898389, COSV64100304; called by muse, varscan2
- SCML1 | c.403G>A p.E135K (on ENST00000380041 / NM_001037540.3; = p.E108K on NM_006746.6) | Missense Mutation (SNP) | VAF 56/280 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV66240894; called by muse, mutect2, varscan2
- SERPINA10 | c.804G>T p.M268I | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV56228981; called by muse, mutect2, varscan2
- SETD3 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 75/249 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs771711935, COSV59283870; called by muse, mutect2, varscan2
- SLC16A6 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.622); catalogued as COSV100517267; called by muse, mutect2
- SLC35F5 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.971); catalogued as rs1335220758, COSV55519278; called by muse, mutect2, varscan2
- SMO | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.675); catalogued as COSV50833672; called by muse, mutect2, varscan2
- SPDL1 | c.1032+1G>A p.X344_splice | Splice Site (SNP) | VAF 51/169 reads (30%) | catalogued as COSV54668735; called by muse, mutect2, varscan2
- SUFU | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs766370528, COSV64018861; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAF1B | c.478C>T p.L160F | Missense Mutation (SNP) | VAF 57/246 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.216); catalogued as COSV55157878; called by muse, mutect2, varscan2
- TLN2 | c.7362G>T p.M2454I | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV60891972; called by muse, mutect2
- TMEM132D | c.1553C>T p.T518M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as rs376007280; called by mutect2, varscan2
- TNC | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.155); catalogued as rs796604731, COSV60787054; called by muse, mutect2, varscan2
- TNXB | c.5168G>A p.R1723H (on ENST00000647633; = p.R1476H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.973); catalogued as rs752343940, COSV64483029; called by muse, mutect2, varscan2
- TUT4 | c.1348C>A p.H450N | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV57116519; called by muse, mutect2, varscan2
- ZFHX4 | c.8533C>G p.L2845V | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.458); catalogued as rs147468121, COSV51469060; called by muse, mutect2, varscan2
- ZKSCAN7 | c.2032C>T p.L678F | Missense Mutation (SNP) | VAF 164/372 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV56273510; called by muse, mutect2, varscan2
- ZMYM4 | c.3596C>T p.S1199L | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV58913598; called by muse, mutect2, varscan2
- ZNF286A | c.1525C>T p.L509F | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.972); catalogued as COSV101224752; called by muse, mutect2
- ZNF483 | c.1999G>C p.E667Q | Missense Mutation (SNP) | VAF 74/353 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV58516288; called by muse, mutect2, varscan2
- ZNF506 | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as rs774609179, COSV71354499; called by muse, mutect2, varscan2
- ZNF587 | c.1598C>G p.S533C | Missense Mutation (SNP) | VAF 105/442 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as rs552665720, COSV57149528; called by muse, mutect2, varscan2
- ZNF677 | c.932G>A p.R311K | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV100447731, COSV61720875; called by muse, mutect2
- ZWILCH | c.245C>G p.S82C | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV57181471; called by muse, mutect2, varscan2
- NF1 | c.8084dup p.P2696Tfs*14 (on ENST00000358273 / NM_001042492.3; = p.P2675Tfs*14 on NM_000267.3) | Frame Shift Ins (INS) | VAF 51/172 reads (30%) | called by mutect2, pindel, varscan2
- ABCB4 | c.1545C>A p.I515= | Silent (SNP) | VAF 26/107 reads (24%) | catalogued as COSV55938026; called by muse, mutect2, varscan2
- ADCY9 | c.1023C>T p.I341= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV53578074; called by muse, mutect2, varscan2
- AMIGO2 | c.996G>A p.E332= | Silent (SNP) | VAF 25/213 reads (12%) | catalogued as COSV56974823; called by muse, mutect2, varscan2
- ANK2 | c.9474G>A p.P3158= | Silent (SNP) | VAF 38/179 reads (21%) | catalogued as rs145111737, COSV52177219; ClinVar: likely benign; called by muse, mutect2, varscan2
- AP1G1 | c.687C>T p.S229= | Silent (SNP) | VAF 19/127 reads (15%) | catalogued as rs772009988, COSV55491944; called by muse, mutect2, varscan2
- ARHGAP31 | c.2613C>T p.V871= | Silent (SNP) | VAF 30/362 reads (8%) | catalogued as rs377529099; called by muse, mutect2
- B4GALT7 | c.330C>G p.V110= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as COSV50354098; called by muse, mutect2, varscan2
- CACNA1A | c.4377G>A p.V1459= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV64203777; called by muse, mutect2, varscan2
- CALCOCO1 | c.1287G>A p.L429= | Silent (SNP) | VAF 27/267 reads (10%) | catalogued as COSV100017255; called by muse, mutect2
- CDCP1 | c.921G>T p.G307= | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as COSV56105599, COSV56106631; called by muse, mutect2, varscan2
- CDH8 | c.1749T>C p.N583= | Silent (SNP) | VAF 27/148 reads (18%) | catalogued as COSV54881291; called by muse, mutect2, varscan2
- DCLK1 | c.651C>T p.L217= | Silent (SNP) | VAF 33/142 reads (23%) | catalogued as COSV55196355; called by muse, mutect2, varscan2
- DSTYK | c.1635C>T p.I545= | Silent (SNP) | VAF 39/214 reads (18%) | catalogued as COSV65687264; called by muse, mutect2, varscan2
- EHD2 | c.1338G>C p.V446= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV99621847; called by muse, mutect2
- FANCD2 | c.588C>T p.I196= | Silent (SNP) | VAF 14/202 reads (7%) | catalogued as rs1329768362, COSV55049967, COSV99811945; called by muse, mutect2
- HOMER2 | c.567C>A p.T189= (on ENST00000304231 / NM_199330.3; = p.T178= on NM_004839.4) | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV58487103; called by muse, mutect2, varscan2
- ITGA10 | c.999C>T p.F333= | Silent (SNP) | VAF 71/250 reads (28%) | catalogued as COSV100994836; called by muse, mutect2, varscan2
- ITGB6 | c.1635G>T p.V545= | Silent (SNP) | VAF 42/180 reads (23%) | catalogued as COSV51796196; called by muse, mutect2, varscan2
- MED12 | c.5925C>T p.S1975= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV61346552; called by muse, mutect2, varscan2
- MET | c.4038G>A p.G1346= | Silent (SNP) | VAF 39/358 reads (11%) | catalogued as rs886038413, COSV100577149; ClinVar: benign; called by muse, mutect2
- NOP58 | c.1098C>T p.T366= | Silent (SNP) | VAF 51/201 reads (25%) | catalogued as rs773830845, COSV51897514; called by muse, mutect2, varscan2
- NOP9 | c.897C>G p.L299= | Silent (SNP) | VAF 54/242 reads (22%) | catalogued as rs773388123, COSV51866743; called by muse, mutect2, varscan2
- OR5H14 | c.225C>T p.S75= | Silent (SNP) | VAF 383/1048 reads (37%) | catalogued as COSV101454136; called by muse, mutect2
- PFKM | c.780C>T p.I260= | Silent (SNP) | VAF 52/207 reads (25%) | catalogued as COSV56658880; called by muse, mutect2, varscan2
- PKN1 | c.2484C>T p.V828= | Silent (SNP) | VAF 2/13 reads (15%) | called by muse, mutect2
- PLCH2 | c.1575C>T p.I525= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs762250204, COSV53943343, COSV53945951; called by muse, mutect2, varscan2
- PLK3 | c.699G>A p.L233= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs907199002, COSV59500355; called by muse, mutect2, varscan2
- PLXDC1 | c.1119C>T p.F373= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV59552347; called by muse, mutect2, varscan2
- PPP1R26 | c.2859G>A p.V953= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV63356317; called by muse, mutect2, varscan2
- PRKG2 | c.177G>A p.S59= | Silent (SNP) | VAF 47/140 reads (34%) | catalogued as rs1463026433, COSV52322516; called by muse, mutect2, varscan2
- RASAL2 | c.399C>T p.V133= | Silent (SNP) | VAF 12/153 reads (8%) | catalogued as rs928618250, COSV100862554; called by muse, mutect2
- RBM33 | c.2850G>A p.A950= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs149419607; called by muse, mutect2, varscan2
- RFX6 | c.2220C>T p.F740= | Silent (SNP) | VAF 12/152 reads (8%) | catalogued as COSV100263587; called by muse, mutect2
- RMND1 | c.471C>A p.S157= | Silent (SNP) | VAF 11/159 reads (7%) | catalogued as COSV100323607; called by muse, mutect2
- SIGLEC5 | c.1107G>A p.E369= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV55781397; called by muse, mutect2, varscan2
- SLITRK2 | c.120C>T p.N40= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as COSV59427014; called by muse, mutect2, varscan2
- STEAP1 | c.18C>T p.D6= | Silent (SNP) | VAF 36/171 reads (21%) | catalogued as COSV51882213; called by muse, mutect2, varscan2
- SYNJ2 | c.3933C>G p.A1311= | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as COSV62898782; called by muse, mutect2, varscan2
- TGM2 | c.1386G>A p.L462= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV63931879; called by muse, mutect2, varscan2
- TLR9 | c.2628C>T p.F876= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs754160300, COSV62347485; called by muse, mutect2, varscan2
- TNFSF15 | c.751C>T p.L251= | Silent (SNP) | VAF 48/248 reads (19%) | catalogued as COSV65010500; called by muse, mutect2, varscan2
- ULBP1 | c.721C>T p.L241= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV99998100; called by muse, mutect2
- ZBTB8OS | c.36C>T p.V12= | Silent (SNP) | VAF 33/137 reads (24%) | catalogued as COSV59386005; called by muse, mutect2, varscan2
- ZC3HAV1 | c.333G>A p.E111= | Silent (SNP) | VAF 31/107 reads (29%) | catalogued as COSV54297922; called by muse, mutect2, varscan2
- ZNF286A | c.1527C>T p.L509= | Silent (SNP) | VAF 42/146 reads (29%) | catalogued as rs1302381252, COSV101224753; called by muse, mutect2
- CD300LD | chr17:74592481 G>A | 5'Flank (SNP) | VAF 33/194 reads (17%) | catalogued as rs768145771; called by muse, mutect2, varscan2
- CGB7 | c.-1G>T | 5'UTR (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100655029; called by mutect2, varscan2
- PIK3CD | c.-138+2031G>A | Intron (SNP) | VAF 27/117 reads (23%) | catalogued as rs571954874, COSV66098810; called by muse, mutect2, varscan2
- SSPOP | n.5787C>T | RNA (SNP) | VAF 5/17 reads (29%) | catalogued as rs1042676944, COSV50488338; called by muse, mutect2, varscan2
- UGT1A10 | c.-1C>T | 5'UTR (SNP) | VAF 35/146 reads (24%) | catalogued as COSV100761304, COSV100761646; called by muse, mutect2, varscan2
- ZBTB37 | chr1:173866650 del ATG | 5'Flank (DEL) | VAF 13/87 reads (15%) | called by mutect2, pindel, varscan2
